Somatic mutation profile of tumor specimen C3L-00008-01 (aliquot CPT0001300005) from CPTAC case C3L-00008, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 58.9 years (21,504 days).
Specimen C3L-00008-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd73e279-9bf9-4ce6-b72b-8d9462a4ba5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00008-32 (Blood Derived Normal), aliquot CPT0000080163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28cac5aa-d3f1-4481-b000-0aab06093ae3

The open-access MAF lists 593 somatic variants for this specimen: 381 protein-altering or splice-affecting, 135 silent, 77 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 247, Silent 135, Frame Shift Del 90, Intron 36, Frame Shift Ins 14, Nonsense Mutation 13, 3'UTR 13, 5'UTR 11, RNA 9, Splice Site 9, In Frame Del 4, 3'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364dup p.D122Gfs*18 | Frame Shift Ins (INS) | VAF 35/208 reads (17%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ARID1A | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 167/454 reads (37%) | catalogued as rs878853088, COSV61373203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 126/290 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 123/286 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 46/132 reads (35%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- NPC1 | c.2978del p.G993Efs*4 | Frame Shift Del (DEL) | VAF 124/400 reads (31%) | catalogued as rs775915490, CD053590, COSV99342140; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.379G>C p.G127R | Missense Mutation (SNP) | VAF 328/411 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM128490, COSV64289445, COSV64291964; called by muse, mutect2, varscan2
- AACS | c.1460G>C p.C487S | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1443082259; called by muse, mutect2, varscan2
- ABCA12 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 135/371 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs768133744, COSV55981680, COSV99789541; called by muse, varscan2
- ABHD12B | c.1024C>A p.L342M (on ENST00000337334 / NM_001206673.2; = p.L265M on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.401); catalogued as rs1339855621; called by muse, mutect2, varscan2
- ACSF2 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 59/170 reads (35%) | catalogued as rs1020324543; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- AFG3L2 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 86/409 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs532179680; called by muse, mutect2, varscan2
- AGO2 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV55046708; called by muse, mutect2, varscan2
- ALAS2 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs752853849, COSV58188274, COSV58190561; called by muse, mutect2, varscan2
- ALPG | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 132/356 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs776010626; called by muse, varscan2
- AMBRA1 | c.2815C>T p.R939* (on ENST00000458649 / NM_001367468.1; = p.R849* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/78 reads (46%) | catalogued as COSV100093809; called by muse, mutect2, varscan2
- ANK1 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 158/393 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs776721065, COSV55894829; called by muse, mutect2, varscan2
- ANKRD52 | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV99920999; called by muse, mutect2, varscan2
- ARHGAP32 | c.1351C>T p.R451W (on ENST00000310343 / NM_001378025.1; = p.R102W on NM_014715.4) | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565358361; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 87/246 reads (35%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID1B | c.5432del p.G1811Vfs*27 | Frame Shift Del (DEL) | VAF 38/182 reads (21%) | catalogued as COSV51652814; called by mutect2, pindel, varscan2
- ARID1B | c.5999G>A p.W2000* | Nonsense Mutation (SNP) | VAF 60/268 reads (22%) | catalogued as CM1310773, COSV51656309; called by muse, mutect2, varscan2
- ARNT2 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV57582551; called by muse, mutect2, varscan2
- ASTN1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs201773141, COSV56061211, COSV56079326; called by muse, mutect2, varscan2
- ATAD2 | c.2751G>C p.E917D | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs1200940467; called by muse, mutect2, varscan2
- B4GALNT1 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 131/365 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs745356128, COSV57543363; called by muse, mutect2, varscan2
- BMP1 | c.2602del p.V868* | Frame Shift Del (DEL) | VAF 26/125 reads (21%) | catalogued as COSV100114754; called by mutect2, pindel, varscan2
- C1orf167 | c.4049C>T p.A1350V | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.737); catalogued as rs561769924; called by muse, varscan2
- CACNA1I | c.3140C>T p.A1047V | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1200065688; called by muse, mutect2, varscan2
- CCDC110 | c.1531dup p.I511Nfs*3 | Frame Shift Ins (INS) | VAF 22/55 reads (40%) | catalogued as rs755233311; called by mutect2, varscan2
- CD40 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 46/504 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1261429888; ClinVar: uncertain significance; called by muse, mutect2
- CD55 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747373539, COSV58578030; called by muse, mutect2
- CD6 | c.320del p.P107Rfs*9 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as rs1163206029; called by mutect2, pindel
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 51/156 reads (33%) | catalogued as rs1276928429, COSV55666935; called by mutect2, pindel, varscan2
- CDK5 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 103/308 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447016885; called by muse, mutect2, varscan2
- CDSN | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 145/331 reads (44%) | catalogued as rs781189010; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CEP295 | c.5045dup p.S1683Kfs*2 | Frame Shift Ins (INS) | VAF 44/211 reads (21%) | catalogued as rs762289202; called by mutect2, varscan2
- CFAP46 | c.7261C>A p.P2421T | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99584043; called by muse, mutect2
- CHRNA4 | c.1793T>C p.I598T | Missense Mutation (SNP) | VAF 91/380 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1218274358; called by muse, mutect2, varscan2
- CLDN9 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 75/218 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs775867692; called by muse, mutect2, varscan2
- CMTR1 | c.1721C>A p.P574H | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as COSV100990938; called by muse, mutect2, varscan2
- CNTN6 | c.1795G>T p.G599C | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762273126; called by muse, mutect2, varscan2
- COL15A1 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 71/308 reads (23%) | catalogued as COSV100897686; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 62/131 reads (47%) | catalogued as rs762650691; called by mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 63/162 reads (39%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- DCAF8L2 | c.1418A>G p.K473R | Missense Mutation (SNP) | VAF 95/274 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759509987; called by muse, mutect2, varscan2
- DDN | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs748499205, COSV100305036; called by muse, mutect2, varscan2
- DIP2A | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs372554410, COSV59475048; called by muse, mutect2, varscan2
- DLGAP4 | c.2321C>T p.A774V (on ENST00000339266 / NM_001365621.1; = p.A771V on NM_014902.6) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.094); catalogued as rs368916003; called by muse, mutect2, varscan2
- DNAH10 | c.10112C>T p.A3371V (on ENST00000409039; = p.A3310V on NM_207437.3) | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs1363135042; called by muse, mutect2, varscan2
- DNAJB7 | c.884del p.K295Rfs*25 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | catalogued as rs768619916; called by mutect2, varscan2
- DRD5 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs1217885390, COSV58576655; called by muse, mutect2, varscan2
- DTL | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs138274574; called by muse, mutect2, varscan2
- EEF2K | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs183300451; called by muse, mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs1377283633; called by mutect2, varscan2
- EIF3E | c.462del p.F154Lfs*13 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs1554600455; called by mutect2, pindel, varscan2
- ELOC | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV53023460; called by muse, mutect2, varscan2
- EVA1C | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as rs760691808; called by muse, varscan2
- EVPL | c.4892C>T p.A1631V | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1395629047, COSV100044630; called by muse, mutect2, varscan2
- EVPL | c.2349C>G p.I783M | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs372817316; called by muse, mutect2, varscan2
- FAM222B | c.719del p.P240Rfs*3 | Frame Shift Del (DEL) | VAF 114/284 reads (40%) | catalogued as COSV100368550, COSV100368697; called by mutect2, pindel, varscan2
- FAM47C | c.2225C>A p.P742H | Missense Mutation (SNP) | VAF 137/640 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63723841, COSV63725306; called by muse, mutect2, varscan2
- FBN2 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.545); catalogued as rs199868637, COSV52518284; called by muse, mutect2, varscan2
- FCGBP | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 93/179 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs371888217; called by muse, mutect2, varscan2
- FOXM1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs769409425, COSV100700841; called by muse, mutect2, varscan2
- FUNDC2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1557288293; called by muse, mutect2, varscan2
- GALNT6 | c.1108G>A p.G370S | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773414768, COSV100695654; called by muse, mutect2, varscan2
- GEMIN4 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 114/315 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs1438469529; called by muse, mutect2, varscan2
- GPC3 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1569462740, COSV99056797; ClinVar: uncertain significance; called by muse, varscan2
- GRAMD4 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs776152054; called by muse, mutect2, varscan2
- GRM1 | c.2944G>A p.V982M | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV51166468; called by muse, mutect2, varscan2
- GYS1 | c.1325del p.P442Lfs*16 | Frame Shift Del (DEL) | VAF 99/297 reads (33%) | catalogued as rs751494565, COSV54405555; called by mutect2, pindel, varscan2
- HCK | c.9del p.R4_?3 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs755024531; called by mutect2, varscan2
- HDAC9 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs369034418; called by muse, varscan2
- HDGFL1 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 120/296 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100014509; called by muse, mutect2, varscan2
- HIPK2 | c.3479C>T p.P1160L | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV101301629; called by muse, mutect2, varscan2
- HMGCR | c.644G>A p.C215Y | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1237825871; called by muse, mutect2, varscan2
- HPS5 | c.3136del p.Q1046Rfs*4 (on ENST00000349215 / NM_181507.2; = p.Q932Rfs*4 on NM_007216.4) | Frame Shift Del (DEL) | VAF 37/274 reads (14%) | catalogued as rs1564923530; called by mutect2, pindel, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 55/156 reads (35%) | catalogued as rs747841314; called by mutect2, varscan2
- IFFO2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1341639152, COSV69086066; called by muse, mutect2, varscan2
- IGKV3-7 | c.273C>G p.D91E | Missense Mutation (SNP) | VAF 246/441 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.282); catalogued as rs771638124; called by mutect2, varscan2
- INAVA | c.67del p.E23Rfs*90 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs750421792; called by mutect2, pindel
- INO80 | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 29/213 reads (14%) | catalogued as COSV62740894; called by muse, mutect2, varscan2
- INPP4A | c.2294G>A p.R765H (on ENST00000074304 / NM_001134224.1; = p.R726H on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50785056; called by muse, mutect2, varscan2
- INPP5A | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as rs201167385, COSV100704467; called by muse, mutect2, varscan2
- INTS1 | c.5449G>A p.V1817M | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs372736624; called by muse, mutect2, varscan2
- IRF1 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs775766689; called by muse, mutect2, varscan2
- ITGAX | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51650108; called by muse, mutect2, varscan2
- ITPRID1 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs761308636; called by muse, mutect2, varscan2
- JMJD8 | c.441_442del p.F148Sfs*45 | Frame Shift Del (DEL) | VAF 70/234 reads (30%) | catalogued as rs767022246; called by pindel, varscan2
- KIF5B | c.1864dup p.M622Nfs*5 | Frame Shift Ins (INS) | VAF 42/116 reads (36%) | catalogued as rs777526028; called by mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 125/313 reads (40%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KRT20 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 103/228 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1264655750; called by muse, mutect2, varscan2
- KRTAP10-6 | c.669del p.C224Afs*157 | Frame Shift Del (DEL) | VAF 140/693 reads (20%) | catalogued as rs1555926661; called by mutect2, pindel, varscan2
- KRTAP4-9 | c.524G>A p.C175Y | Missense Mutation (SNP) | VAF 132/396 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV66950594; called by muse, varscan2
- LAMA2 | c.8848G>A p.A2950T | Missense Mutation (SNP) | VAF 75/333 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1222567806, COSV101370721; called by muse, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 52/140 reads (37%) | catalogued as rs765287063; called by mutect2, varscan2
- LRP4 | c.5063C>T p.T1688M | Missense Mutation (SNP) | VAF 99/304 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs766225540, COSV66137951; called by muse, varscan2
- MAPK12 | c.427-5dup | Splice Region (INS) | VAF 21/69 reads (30%) | catalogued as rs752922316; called by mutect2, pindel, varscan2
- MED13 | c.5120A>G p.Y1707C | Missense Mutation (SNP) | VAF 141/340 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1199783791; called by muse, mutect2, varscan2
- MEN1 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 125/316 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs767854775, COSV53643766; called by muse, mutect2, varscan2
- MEP1A | c.2161A>G p.M721V | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs926587361; called by muse, mutect2, varscan2
- MFN2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 96/386 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as rs560470663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP8 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 108/283 reads (38%) | catalogued as rs780366606, COSV52630820; called by muse, mutect2, varscan2
- MMP9 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs1408103367, COSV63433818; called by muse, mutect2, varscan2
- MS4A1 | c.708del p.E237Nfs*6 | Frame Shift Del (DEL) | VAF 24/158 reads (15%) | catalogued as rs779922206; called by mutect2, varscan2
- MS4A10 | c.611A>G p.D204G | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.431); catalogued as rs1250555116; called by muse, mutect2, varscan2
- MS4A12 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV50014311, COSV99188741; called by muse, varscan2
- MSLN | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 78/196 reads (40%) | catalogued as rs776910001; called by muse, mutect2, varscan2
- MTRF1 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs780827281, COSV65263944; called by muse, mutect2, varscan2
- MUC5B | c.17017G>A p.E5673K | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs577423157; called by muse, mutect2, varscan2
- MUL1 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs1222136642; called by muse, mutect2, varscan2
- MYLK3 | c.1205C>G p.P402R | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs761650400, COSV67363438; called by muse, mutect2, varscan2
- NAIF1 | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66091475; called by muse, mutect2, varscan2
- NALCN | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs145128255; called by muse, mutect2, varscan2
- NKX6-3 | c.157del p.H53Tfs*7 | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | catalogued as rs1249850082; called by mutect2, pindel, varscan2
- NPRL2 | c.585+2T>C p.X195_splice | Splice Site (SNP) | VAF 39/89 reads (44%) | catalogued as COSV51604024; called by muse, mutect2, varscan2
- NSUN2 | c.1115A>G p.Q372R | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs772137602; called by muse, mutect2, varscan2
- NWD1 | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.883); catalogued as COSV60351916; called by muse, mutect2
- OBSCN | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 135/313 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.106); catalogued as rs866556298; called by muse, mutect2, varscan2
- ODF3L2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.095); catalogued as rs1043189275; called by muse, mutect2, varscan2
- OLFM2 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 170/449 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV53431287; called by muse, mutect2, varscan2
- OR10J3 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 76/357 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs781120025; called by muse, mutect2, varscan2
- OR1D5 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 97/546 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529670673, COSV73859482; called by muse, mutect2, varscan2
- OR5J2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs779578731; called by muse, mutect2, varscan2
- PABPN1 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as rs535276533; called by muse, mutect2
- PCDHB5 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs561581411, COSV50658890; called by muse, mutect2, varscan2
- PCDHB6 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 84/319 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.26); catalogued as COSV50700643; called by muse, mutect2, varscan2
- PCDHB8 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 217/541 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs782064898, COSV99177056; called by muse, mutect2, varscan2
- PCDHGA3 | c.2314del p.Q772Sfs*21 | Frame Shift Del (DEL) | VAF 111/387 reads (29%) | catalogued as rs1184509828, COSV53911077; called by mutect2, pindel, varscan2
- PCDHGB6 | c.680A>G p.H227R | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1561715935; called by muse, mutect2, varscan2
- PDX1 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs981314993; called by muse, mutect2
- PGR | c.2488A>C p.I830L | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV99677413; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 40/88 reads (45%) | catalogued as rs769717544; called by mutect2, varscan2
- PIK3R5 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as rs753712971, COSV52657556; called by muse, mutect2, varscan2
- PPFIA4 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as rs529792187; called by muse, mutect2, varscan2
- PPL | c.1362dup p.T455Hfs*4 | Frame Shift Ins (INS) | VAF 30/92 reads (33%) | catalogued as rs753902804; called by mutect2, varscan2
- PPM1M | c.397_399del p.K133del (on ENST00000296487; = p.K294del on NM_144641.4) | In Frame Del (DEL) | VAF 87/274 reads (32%) | catalogued as rs766564505; called by mutect2, pindel, varscan2
- PPP1R9B | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as rs781329499; called by muse, mutect2, varscan2
- PRC1 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs373811756; called by muse, mutect2
- PRR12 | c.1418G>A p.R473H (on ENST00000615927; = p.R1294H on NM_020719.3) | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1166432435, COSV69816922; called by muse, mutect2, varscan2
- PSD4 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55530548; called by muse, mutect2, varscan2
- RAG2 | c.1519A>G p.K507E | Missense Mutation (SNP) | VAF 108/237 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV57556424; called by muse, mutect2, varscan2
- RALGPS2 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.131); catalogued as rs753369086, COSV62678813; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 54/139 reads (39%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM47 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 156/340 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1158990104; called by muse, mutect2, varscan2
- RDH16 | c.832del p.R278Vfs*17 | Frame Shift Del (DEL) | VAF 76/326 reads (23%) | catalogued as rs755216247; called by mutect2, pindel, varscan2
- RECQL4 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99467126; called by muse, mutect2, varscan2
- RGMB | c.570A>G p.I190M (on ENST00000513185 / NM_001366508.1; = p.I231M on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759967528; called by muse, mutect2, varscan2
- RHPN2 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 126/327 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs369196164; called by muse, mutect2, varscan2
- RYBP | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 56/335 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1382885623, COSV72180845; called by muse, mutect2, varscan2
- SAP130 | c.1466del p.L489Cfs*48 | Frame Shift Del (DEL) | VAF 38/166 reads (23%) | catalogued as rs1198584290; called by mutect2, pindel, varscan2
- SBNO2 | c.3644G>A p.R1215H | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1330823543; called by muse, mutect2, varscan2
- SEPTIN11 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as rs1271441074; called by muse, mutect2
- SKIV2L | c.1339C>T p.H447Y | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs778184511, COSV64813904; called by muse, mutect2, varscan2
- SLC29A3 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs142991278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs759883814, COSV56092392; called by pindel, varscan2
- SLC9A3 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99375756; called by muse, mutect2, varscan2
- SMIM1 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1288017221; called by muse, mutect2, varscan2
- SMYD4 | c.2260G>A p.G754R | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141269002; called by muse, mutect2, varscan2
- SPIRE2 | c.1391del p.P464Qfs*53 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as rs1187128946; called by mutect2, pindel, varscan2
- SPTBN2 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs750308908; called by muse, mutect2, varscan2
- SRPX | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59438124; called by muse, mutect2, varscan2
- STARD13 | c.1127C>T p.P376L (on ENST00000336934 / NM_001243476.3; = p.P258L on NM_052851.3) | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs771360121; called by muse, mutect2, varscan2
- THAP3 | c.548del p.L183Wfs*3 (on ENST00000054650 / NM_001195753.1; = p.L182Wfs*3 on NM_001195752.1) | Frame Shift Del (DEL) | VAF 178/492 reads (36%) | catalogued as COSV50011311; called by mutect2, pindel, varscan2
- TLL2 | c.1397del p.G466Efs*3 | Frame Shift Del (DEL) | VAF 27/139 reads (19%) | catalogued as rs1261395235, COSV100780097; called by mutect2, pindel, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs760930120; called by mutect2, varscan2
- TMEM132C | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious, low confidence (0); catalogued as rs1297162275; called by muse, mutect2, varscan2
- TMTC1 | c.887C>A p.P296H (on ENST00000539277 / NM_001193451.2; = p.P188H on NM_175861.3) | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as rs575968894; called by muse, mutect2, varscan2
- TMTC2 | c.1238del p.F413Sfs*6 | Frame Shift Del (DEL) | VAF 28/208 reads (13%) | catalogued as COSV58258155; called by mutect2, pindel, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 72/200 reads (36%) | catalogued as rs770561785; called by mutect2, varscan2
- TRPM3 | c.733C>T p.R245* (on ENST00000357533 / NM_001366142.2; = p.R90* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 65/188 reads (35%) | catalogued as rs1165144451; called by muse, varscan2
- TRPM4 | c.2295del p.R766Afs*15 | Frame Shift Del (DEL) | VAF 24/300 reads (8%) | catalogued as rs748307155; called by mutect2, pindel
- TSNAXIP1 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 185/440 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54649758, COSV54649777; called by muse, mutect2, varscan2
- TTC7B | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1290652526, COSV60627039; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL12 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as rs771565831, COSV99333775; called by muse, mutect2, varscan2
- TTYH2 | c.1290_1292dup p.D431dup | In Frame Ins (INS) | VAF 30/182 reads (16%) | catalogued as rs773382990; called by mutect2, varscan2
- TULP3 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs1325526741; called by muse, mutect2, varscan2
- UCN | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs1227861621; called by muse, mutect2, varscan2
- UROS | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs776171817; called by muse, mutect2
- VPREB1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 149/317 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as rs1423186027; called by muse, mutect2, varscan2
- VPS37C | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs1261181738; called by muse, mutect2, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs756173793; called by mutect2, varscan2
- ZC3H18 | c.2406del p.Q804Sfs*15 | Frame Shift Del (DEL) | VAF 103/271 reads (38%) | catalogued as rs750724166; called by mutect2, pindel, varscan2
- ZNF133 | c.195del p.K65Nfs*122 (on ENST00000316358 / NM_001352454.2; = p.K65Nfs*121 on NM_003434.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 60/164 reads (37%) | catalogued as rs753775995, COSV60366352; called by mutect2, varscan2
- ZNF638 | c.4185G>T p.K1395N | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as COSV52486817; called by muse, mutect2, varscan2
- ZNF668 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.885); catalogued as rs980309193; called by muse, mutect2
- ZNF74 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1444996838; called by muse, mutect2, varscan2
- ZNF804A | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs767246808, COSV100166890; called by muse, varscan2
- ABCC1 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 136/368 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ABHD4 | c.527T>A p.L176H | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABTB1 | c.753del p.E252Sfs*102 (on ENST00000232744 / NM_172027.3; = p.E110Sfs*102 on NM_032548.3) | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADAMTS14 | c.3091A>G p.R1031G | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRA1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- AFF2 | c.82del p.R28Gfs*30 | Frame Shift Del (DEL) | VAF 21/112 reads (19%) | called by mutect2, varscan2
- AKAP9 | c.5920dup p.T1974Nfs*2 (on ENST00000359028; = p.T1942Nfs*2 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 107/283 reads (38%) | called by mutect2, pindel, varscan2
- AMBRA1 | c.1675_1684del p.N559Vfs*4 (on ENST00000458649 / NM_001367468.1; = p.N469Vfs*4 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 117/374 reads (31%) | called by pindel, varscan2
- ANKRD23 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANO6 | c.257del p.K86Rfs*25 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | called by mutect2, pindel, varscan2
- APC2 | c.3605C>A p.P1202H | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP25 | c.1813G>A p.A605T (on ENST00000409202 / NM_001007231.3; = p.A597T on NM_014882.3) | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- ARHGEF33 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ARID4B | c.2630A>G p.K877R | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- ATAD2 | c.4030del p.S1344Vfs*15 | Frame Shift Del (DEL) | VAF 40/99 reads (40%) | called by mutect2, varscan2
- ATF2 | c.318del p.M107Cfs*3 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | called by mutect2, pindel, varscan2
- B4GALT6 | c.798del p.F266Lfs*4 | Frame Shift Del (DEL) | VAF 50/148 reads (34%) | called by pindel, varscan2
- BTRC | c.1130A>G p.N377S (on ENST00000370187 / NM_033637.4; = p.N341S on NM_003939.5) | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- C12orf50 | c.563dup p.T189Dfs*2 | Frame Shift Ins (INS) | VAF 14/136 reads (10%) | called by pindel, varscan2
- CANT1 | c.347A>G p.E116G | Missense Mutation (SNP) | VAF 135/628 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASP12 | c.411del p.E138Rfs*12 | Frame Shift Del (DEL) | VAF 35/94 reads (37%) | called by mutect2, pindel, varscan2
- CDH7 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 170/436 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 33/91 reads (36%) | called by mutect2, pindel
- CEP295 | c.3371A>G p.Q1124R | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- CEP350 | c.8228del p.K2743Sfs*12 | Frame Shift Del (DEL) | VAF 94/271 reads (35%) | called by mutect2, pindel, varscan2
- CHD9 | c.1744del p.T582Qfs*7 | Frame Shift Del (DEL) | VAF 40/110 reads (36%) | called by mutect2, pindel
- CLCN2 | c.1879A>G p.I627V | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CNIH4 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); called by muse, varscan2
- CNTN6 | c.1638del p.G547Efs*16 | Frame Shift Del (DEL) | VAF 38/82 reads (46%) | called by mutect2, varscan2
- COL16A1 | c.3763G>T p.G1255* | Nonsense Mutation (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- COL7A1 | c.1208T>C p.V403A | Missense Mutation (SNP) | VAF 80/468 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CREBBP | c.5807G>T p.G1936V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CUEDC2 | c.445del p.V149Wfs*35 | Frame Shift Del (DEL) | VAF 43/108 reads (40%) | called by mutect2, pindel, varscan2
- CWF19L2 | c.1398del p.E467Nfs*22 | Frame Shift Del (DEL) | VAF 35/110 reads (32%) | called by mutect2, pindel
- CXCR6 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DCAF1 | c.2345G>A p.S782N | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DCAF12L2 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- DDI1 | c.700G>C p.A234P | Missense Mutation (SNP) | VAF 103/247 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX51 | c.1912C>G p.L638V | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- DHX32 | c.558T>A p.D186E | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- DHX9 | c.811-1G>T p.X271_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | called by muse, varscan2
- DNAH10 | c.8434G>A p.D2812N (on ENST00000409039; = p.D2751N on NM_207437.3) | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- DNAH14 | c.4737C>G p.D1579E (on ENST00000445597; = p.D1984E on NM_001367479.1) | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUXB | c.441A>G p.Q147= | Splice Region (SNP) | VAF 56/130 reads (43%) | called by muse, mutect2, varscan2
- EHMT2 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EIF2B4 | c.1398G>C p.K466N (on ENST00000347454 / NM_001034116.2; = p.K465N on NM_015636.3) | Missense Mutation (SNP) | VAF 68/434 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPB41L1 | c.1993del p.A665Pfs*31 | Frame Shift Del (DEL) | VAF 24/178 reads (13%) | called by mutect2, pindel, varscan2
- ERCC5 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EXOC3L4 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- FAM171A1 | c.2602C>A p.Q868K | Missense Mutation (SNP) | VAF 53/276 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- FAM20A | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 77/150 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FASN | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 67/464 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCAMR | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2
- FCGBP | c.10625G>A p.S3542N | Missense Mutation (SNP) | VAF 128/382 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FER1L6 | c.1949del p.K650Sfs*5 | Frame Shift Del (DEL) | VAF 51/147 reads (35%) | called by mutect2, pindel, varscan2
- FOXL3 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FRMD4B | c.1994C>T p.T665I | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- GCFC2 | c.555T>G p.H185Q | Missense Mutation (SNP) | VAF 111/330 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- GCFC2 | c.554A>C p.H185P | Missense Mutation (SNP) | VAF 111/333 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLB1L2 | c.1420del p.L474* | Frame Shift Del (DEL) | VAF 53/175 reads (30%) | called by mutect2, pindel, varscan2
- GLTPD2 | c.514del p.R172Gfs*160 | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | called by mutect2, pindel, varscan2
- GYS1 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- H3C12 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- HCFC1 | c.6019_6021dup p.S2008dup | In Frame Ins (INS) | VAF 27/157 reads (17%) | called by mutect2, pindel, varscan2
- HGS | c.1693del p.L565Cfs*45 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- IGSF10 | c.1085dup p.L362Ffs*22 | Frame Shift Ins (INS) | VAF 45/138 reads (33%) | called by mutect2, pindel, varscan2
- INCENP | c.2536G>A p.A846T (on ENST00000394818 / NM_001040694.2; = p.A842T on NM_020238.3) | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ING4 | c.549dup p.S184Lfs*2 (on ENST00000396807 / NM_001127582.2; = p.S183Lfs*2 on NM_016162.4) | Frame Shift Ins (INS) | VAF 20/131 reads (15%) | called by mutect2, pindel, varscan2
- INPP4A | c.224del p.P75Lfs*24 | Frame Shift Del (DEL) | VAF 66/199 reads (33%) | called by mutect2, pindel, varscan2
- INPP4A | c.2434A>G p.R812G (on ENST00000074304 / NM_001134224.1; = p.R773G on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- IQANK1 | c.-4-2A>G | Splice Site (SNP) | VAF 28/142 reads (20%) | called by muse, mutect2, varscan2
- ITGAX | c.2406C>G p.N802K | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- KBTBD11 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNA2 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- KCNK3 | c.827del p.G276Vfs*52 | Frame Shift Del (DEL) | VAF 35/101 reads (35%) | called by mutect2, pindel, varscan2
- KMT2B | c.7934G>T p.G2645V | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT35 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- KRTAP10-4 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 251/700 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, varscan2
- LEF1 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LGALS9 | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 11/276 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2
- LHX3 | c.965C>T p.A322V (on ENST00000371748 / NM_178138.6; = p.A327V on NM_014564.5) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- LRRC63 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2
- MAG | c.1097T>C p.L366P | Missense Mutation (SNP) | VAF 110/317 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MAGEC1 | c.2491G>A p.V831M | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MAPKBP1 | c.3763A>G p.M1255V (on ENST00000456763 / NM_001128608.2; = p.M1249V on NM_014994.3) | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPRE3 | c.543del p.C182Afs*31 | Frame Shift Del (DEL) | VAF 32/82 reads (39%) | called by mutect2, varscan2
- MED24 | c.1038del p.L347Cfs*63 | Frame Shift Del (DEL) | VAF 66/194 reads (34%) | called by mutect2, pindel, varscan2
- MEN1 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MERTK | c.1867T>G p.L623V | Missense Mutation (SNP) | VAF 120/325 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- MIDEAS | c.3073del p.T1025Qfs*68 | Frame Shift Del (DEL) | VAF 155/494 reads (31%) | called by pindel, varscan2
- MLLT6 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MRC1 | c.1033A>G p.T345A | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO3A | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 51/332 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MYOCD | c.684del p.S229Afs*4 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- NOS1 | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOTCH2 | c.1564_1566del p.P522del | In Frame Del (DEL) | VAF 106/267 reads (40%) | called by pindel, varscan2
- NPRL2 | c.420del p.N140Kfs*18 | Frame Shift Del (DEL) | VAF 79/259 reads (31%) | called by mutect2, pindel, varscan2
- NR4A2 | c.325del p.Q109Sfs*5 | Frame Shift Del (DEL) | VAF 31/255 reads (12%) | called by mutect2, pindel, varscan2
- NR4A3 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 133/431 reads (31%) | called by mutect2, pindel, varscan2
- OPLAH | c.2425del p.A809Pfs*10 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | called by mutect2, pindel
- OR2B11 | c.643dup p.L215Pfs*85 | Frame Shift Ins (INS) | VAF 45/195 reads (23%) | called by mutect2, pindel, varscan2
- OR2L13 | c.504C>A p.C168* | Nonsense Mutation (SNP) | VAF 93/218 reads (43%) | called by muse, mutect2, varscan2
- P2RX2 | c.668T>C p.L223P (on ENST00000343948 / NM_170683.4; = p.L151P on NM_012226.5) | Missense Mutation (SNP) | VAF 104/230 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PARK7 | c.503T>G p.I168S | Missense Mutation (SNP) | VAF 186/446 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PARP14 | c.4996del p.T1666Lfs*10 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- PAX1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 157/393 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHAC1 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PCDHGA3 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 95/242 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNX3 | c.4378G>A p.V1460M | Missense Mutation (SNP) | VAF 74/357 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PDX1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHACTR4 | c.1802G>A p.R601H (on ENST00000373839 / NM_001350159.2; = p.R611H on NM_023923.4) | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHYHIP | c.241del p.R81Afs*12 | Frame Shift Del (DEL) | VAF 66/180 reads (37%) | called by mutect2, pindel, varscan2
- PIAS4 | c.673-1G>T p.X225_splice | Splice Site (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- PKD1L3 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKN2 | c.1437del p.F479Lfs*32 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- PKN3 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- PKP4 | c.3014G>T p.G1005V | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHA4 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PLEKHG5 | c.1700_1708del p.R567_R569del (on ENST00000400915 / NM_001042663.3; = p.R530_R532del on NM_020631.6) | In Frame Del (DEL) | VAF 125/319 reads (39%) | called by mutect2, pindel, varscan2
- PLVAP | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNPLA3 | c.1426T>C p.S476P | Missense Mutation (SNP) | VAF 84/185 reads (45%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPEF2 | c.733A>G p.M245V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, mutect2
- PPP4R4 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- PRKD3 | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PROSER3 | c.1391dup p.R465Kfs*55 | Frame Shift Ins (INS) | VAF 34/99 reads (34%) | called by mutect2, pindel, varscan2
- PTPRB | c.5602T>C p.W1868R | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RABEP2 | c.38_43del p.E13_R15delinsG | In Frame Del (DEL) | VAF 34/74 reads (46%) | called by mutect2, pindel, varscan2
- REG4 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REPS1 | c.1439C>A p.P480H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RIN1 | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 124/265 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- RNF103 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 157/377 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ROS1 | c.6175C>A p.L2059M | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- RUFY2 | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SALL3 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SAMD4A | c.871del p.L291Cfs*7 | Frame Shift Del (DEL) | VAF 67/363 reads (18%) | called by mutect2, pindel, varscan2
- SARDH | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCAF4 | c.2156del p.P719Lfs*29 | Frame Shift Del (DEL) | VAF 23/193 reads (12%) | called by mutect2, pindel, varscan2
- SCN4A | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SEC61B | c.162del p.M55Cfs*22 | Frame Shift Del (DEL) | VAF 34/128 reads (27%) | called by mutect2, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- SGPP2 | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SH3PXD2A | c.427+1G>A p.X143_splice | Splice Site (SNP) | VAF 44/162 reads (27%) | called by muse, mutect2, varscan2
- SHC1 | c.1338del p.N447Ifs*15 (on ENST00000368445 / NM_183001.5; = p.N338Ifs*15 on NM_003029.5) | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | called by mutect2, pindel, varscan2
- SIPA1L3 | c.3263C>T p.A1088V | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC44A2 | c.257_260del p.Y86Cfs*7 | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | called by mutect2, pindel, varscan2
- SMTN | c.1158del p.S387Vfs*14 | Frame Shift Del (DEL) | VAF 115/299 reads (38%) | called by mutect2, pindel, varscan2
- SNRPA1 | c.599A>G p.D200G | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2
- SOCS5 | c.121A>G p.K41E | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPRED2 | c.658del p.R220Gfs*6 | Frame Shift Del (DEL) | VAF 27/168 reads (16%) | called by mutect2, pindel, varscan2
- SPX | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 94/230 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- STAB1 | c.827G>A p.C276Y | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAB1 | c.7166T>C p.L2389P | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SUSD1 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.014); called by muse, mutect2
- SYNDIG1 | c.218T>A p.L73Q | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SZT2 | c.5500dup p.L1834Pfs*37 (on ENST00000634258 / NM_001365999.1; = p.L1777Pfs*37 on NM_015284.4) | Frame Shift Ins (INS) | VAF 35/94 reads (37%) | called by mutect2, pindel, varscan2
- TAF1L | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.054); called by muse, mutect2
- THOC2 | c.2413A>G p.N805D | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- THRAP3 | c.1311del p.A438Lfs*20 | Frame Shift Del (DEL) | VAF 62/177 reads (35%) | called by mutect2, pindel, varscan2
- TMEM39B | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMTC3 | c.470del p.L157Cfs*13 | Frame Shift Del (DEL) | VAF 15/107 reads (14%) | called by mutect2, pindel, varscan2
- TNPO3 | c.2541del p.Y848Ifs*25 | Frame Shift Del (DEL) | VAF 90/255 reads (35%) | called by mutect2, pindel, varscan2
- TPK1 | c.181_182dup p.S62Kfs*52 | Frame Shift Ins (INS) | VAF 48/130 reads (37%) | called by mutect2, varscan2
- TPO | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 189/442 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TPST2 | c.130del p.A44Pfs*10 | Frame Shift Del (DEL) | VAF 16/132 reads (12%) | called by mutect2, pindel
- TRAK2 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 22/299 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.129); called by muse, mutect2
- TRIM14 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRPM1 | c.4007dup p.D1337Rfs*9 | Frame Shift Ins (INS) | VAF 153/434 reads (35%) | called by mutect2, pindel, varscan2
- TTC17 | c.1612A>G p.S538G | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.034); called by muse, mutect2
- TTC22 | c.749G>T p.W250L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTLL11 | c.927G>T p.W309C | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TTLL8 | c.2108G>A p.S703N | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- U2SURP | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR4 | c.14752G>A p.G4918R | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UMPS | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.9560_9570+9del p.X3187_splice | Splice Site (DEL) | VAF 20/154 reads (13%) | called by mutect2, pindel
- WDR27 | c.1481+2T>C p.X494_splice | Splice Site (SNP) | VAF 41/118 reads (35%) | called by muse, mutect2, varscan2
- WNT4 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 129/300 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- YLPM1 | c.5778del p.F1928Sfs*33 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- ZCCHC7 | c.1068del p.G357Afs*38 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | called by mutect2, pindel
- ZFX | c.1789del p.T597Lfs*16 | Frame Shift Del (DEL) | VAF 99/312 reads (32%) | called by mutect2, pindel, varscan2
- ZNF536 | c.3137G>T p.R1046L | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF554 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF628 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 160/435 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF649 | c.1375del p.D459Ifs*3 | Frame Shift Del (DEL) | VAF 90/306 reads (29%) | called by mutect2, pindel, varscan2
- ZNF860 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 14/373 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2
- ZP2 | c.1099+2T>C p.X367_splice | Splice Site (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2
- ZSWIM9 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 154/407 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ABHD17A | c.804G>A p.E268= (on ENST00000292577 / NM_001130111.2; = p.E319= on NM_031213.4) | Silent (SNP) | VAF 58/239 reads (24%) | called by muse, mutect2, varscan2
- ACP5 | c.813G>A p.Q271= | Silent (SNP) | VAF 158/372 reads (42%) | called by muse, mutect2, varscan2
- ADAM12 | c.522C>T p.S174= | Silent (SNP) | VAF 109/286 reads (38%) | catalogued as rs755139050; called by muse, mutect2, varscan2
- ADAMTS7 | c.2079C>T p.N693= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as rs774169849, COSV101183325; called by muse, mutect2, varscan2
- AFF2 | c.1464C>T p.S488= | Silent (SNP) | VAF 56/159 reads (35%) | called by muse, mutect2, varscan2
- AGAP9 | c.912C>T p.Y304= | Silent (SNP) | VAF 84/800 reads (11%) | called by muse, mutect2, varscan2
- AMBRA1 | c.1743C>T p.T581= (on ENST00000458649 / NM_001367468.1; = p.T491= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 117/326 reads (36%) | catalogued as rs776448711; called by muse, varscan2
- AMOT | c.2088G>A p.L696= (on ENST00000371959 / NM_001113490.1; = p.L287= on NM_133265.3) | Silent (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2514G>A p.L838= | Silent (SNP) | VAF 55/167 reads (33%) | catalogued as COSV51840199; called by muse, mutect2, varscan2
- ANKRD36 | c.2079T>C p.T693= | Silent (SNP) | VAF 91/225 reads (40%) | called by muse, mutect2, varscan2
- AP2A1 | c.2289C>T p.I763= | Silent (SNP) | VAF 54/366 reads (15%) | catalogued as rs376682843; called by muse, varscan2
- B3GALT1 | c.711G>A p.S237= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as rs773363253; called by muse, varscan2
- BARX2 | c.474G>A p.L158= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- BBOX1 | c.1084C>T p.L362= | Silent (SNP) | VAF 9/262 reads (3%) | called by muse, mutect2
- BCL11B | c.1509C>T p.S503= (on ENST00000357195 / NM_001282237.2; = p.S432= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/199 reads (38%) | catalogued as rs995562955; called by muse, mutect2, varscan2
- BICD2 | c.675G>A p.Q225= | Silent (SNP) | VAF 45/285 reads (16%) | called by muse, mutect2, varscan2
- BRI3BP | c.453C>T p.H151= | Silent (SNP) | VAF 159/377 reads (42%) | called by muse, mutect2, varscan2
- C6orf15 | c.153C>T p.S51= | Silent (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- CACNA1G | c.30C>T p.A10= | Silent (SNP) | VAF 143/409 reads (35%) | called by muse, mutect2, varscan2
- CARD11 | c.2139G>T p.L713= | Silent (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2
- CBARP | c.1650C>T p.R550= | Silent (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- CCAR1 | c.1677G>A p.G559= | Silent (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- CCND3 | c.120C>A p.P40= | Silent (SNP) | VAF 45/127 reads (35%) | called by muse, mutect2, varscan2
- CDAN1 | c.2842C>T p.L948= | Silent (SNP) | VAF 151/352 reads (43%) | called by muse, mutect2, varscan2
- CHST8 | c.774C>T p.R258= | Silent (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- CLCN7 | c.1989G>T p.V663= | Silent (SNP) | VAF 91/277 reads (33%) | called by muse, mutect2, varscan2
- CLDN7 | c.102C>A p.S34= | Silent (SNP) | VAF 165/418 reads (39%) | called by muse, mutect2, varscan2
- COL16A1 | c.3957C>T p.T1319= | Silent (SNP) | VAF 71/175 reads (41%) | catalogued as rs368113432; called by muse, mutect2, varscan2
- COL22A1 | c.264G>A p.T88= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs1195461317, COSV57347850; called by muse, mutect2, varscan2
- COL5A1 | c.1401C>T p.I467= | Silent (SNP) | VAF 74/176 reads (42%) | catalogued as rs1452745305, COSV65668181; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL5A1 | c.4818C>T p.D1606= | Silent (SNP) | VAF 95/295 reads (32%) | catalogued as rs190912679; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.6948A>G p.S2316= (on ENST00000312481; = p.S2312= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/235 reads (14%) | called by muse, mutect2, varscan2
- CRHR1 | c.711C>T p.G237= (on ENST00000398285 / NM_001145146.2; = p.G208= on NM_004382.5) | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as rs368177064, COSV99524221; called by muse, mutect2, varscan2
- CRMP1 | c.654G>A p.T218= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as rs765147252; called by muse, mutect2, varscan2
- CTU2 | c.1152C>T p.S384= | Silent (SNP) | VAF 86/327 reads (26%) | catalogued as rs147606000; called by muse, mutect2, varscan2
- D2HGDH | c.801G>A p.T267= | Silent (SNP) | VAF 64/287 reads (22%) | catalogued as rs1309942658; called by muse, varscan2
- DBH | c.984C>T p.L328= | Silent (SNP) | VAF 213/445 reads (48%) | catalogued as COSV55042364; called by muse, mutect2, varscan2
- DGKE | c.942C>T p.N314= | Silent (SNP) | VAF 93/237 reads (39%) | catalogued as rs749415630, COSV52351847; called by muse, mutect2, varscan2
- EBF1 | c.381C>T p.Y127= | Silent (SNP) | VAF 58/177 reads (33%) | catalogued as COSV58181152; called by muse, mutect2, varscan2
- EIF3A | c.1350T>C p.I450= | Silent (SNP) | VAF 17/163 reads (10%) | called by muse, mutect2, varscan2
- EMC8 | c.528C>T p.D176= | Silent (SNP) | VAF 79/204 reads (39%) | catalogued as rs1318227480; called by muse, mutect2, varscan2
- ERCC2 | c.270G>A p.L90= | Silent (SNP) | VAF 112/483 reads (23%) | called by muse, mutect2, varscan2
- FAM170B | c.282C>T p.C94= | Silent (SNP) | VAF 36/184 reads (20%) | called by muse, mutect2, varscan2
- FAM90A1 | c.618T>C p.A206= | Silent (SNP) | VAF 303/788 reads (38%) | called by muse, mutect2, varscan2
- FLNB | c.3927T>C p.D1309= | Silent (SNP) | VAF 131/284 reads (46%) | called by muse, mutect2, varscan2
- FOXD2 | c.1146G>A p.L382= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as rs1308194295; called by muse, mutect2, varscan2
- FZD10 | c.973C>T p.L325= | Silent (SNP) | VAF 139/331 reads (42%) | catalogued as rs755696632; called by muse, mutect2, varscan2
- FZD7 | c.1521G>A p.T507= | Silent (SNP) | VAF 25/200 reads (13%) | catalogued as rs750464553, COSV53810564; called by muse, mutect2, varscan2
- GABRP | c.510C>T p.D170= | Silent (SNP) | VAF 58/168 reads (35%) | called by muse, mutect2, varscan2
- GAD2 | c.165G>A p.P55= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs763695378, COSV52156971; called by muse, mutect2, varscan2
- GALNT12 | c.640C>T p.L214= | Silent (SNP) | VAF 75/298 reads (25%) | catalogued as COSV100899191; called by muse, mutect2, varscan2
- GBA | c.846A>G p.G282= | Silent (SNP) | VAF 215/617 reads (35%) | called by muse, mutect2, varscan2
- GGA3 | c.186G>A p.A62= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as rs751018627, COSV55457274, COSV99822036; called by muse, mutect2, varscan2
- GJD4 | c.315G>A p.A105= | Silent (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- GOLGA3 | c.1038C>T p.N346= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs139919885; called by muse, mutect2, varscan2
- GPR158 | c.393C>T p.H131= | Silent (SNP) | VAF 111/284 reads (39%) | called by muse, mutect2, varscan2
- HECTD1 | c.3198G>A p.R1066= | Silent (SNP) | VAF 55/137 reads (40%) | called by muse, mutect2, varscan2
- HMX3 | c.597C>T p.S199= | Silent (SNP) | VAF 63/154 reads (41%) | catalogued as rs750592257; called by muse, mutect2, varscan2
- HSPG2 | c.2361G>A p.T787= | Silent (SNP) | VAF 102/238 reads (43%) | catalogued as rs750614056, COSV101021189; called by muse, mutect2, varscan2
- HTT | c.474G>A p.L158= | Silent (SNP) | VAF 48/163 reads (29%) | catalogued as rs759707352; called by muse, mutect2, varscan2
- IGDCC3 | c.678T>G p.T226= | Silent (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- IGHV3-74 | c.237C>T p.Y79= | Silent (SNP) | VAF 14/398 reads (4%) | catalogued as rs761799364; called by muse, mutect2
- IL12B | c.510C>T p.C170= | Silent (SNP) | VAF 36/283 reads (13%) | catalogued as rs771036480, COSV51454347; called by muse, mutect2, varscan2
- IRAK1 | c.687G>T p.A229= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as COSV57655472; called by muse, mutect2, varscan2
- IRX2 | c.846C>T p.P282= | Silent (SNP) | VAF 81/174 reads (47%) | catalogued as COSV57410725; called by muse, mutect2, varscan2
- JAG2 | c.2847C>T p.C949= | Silent (SNP) | VAF 57/165 reads (35%) | catalogued as rs762916197; called by muse, mutect2, varscan2
- KAT7 | c.978G>A p.L326= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV52015501; called by muse, mutect2
- KRBA1 | c.723G>A p.T241= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as rs367848834, COSV99752202; called by muse, mutect2, varscan2
- LLGL2 | c.336G>A p.Q112= | Silent (SNP) | VAF 65/166 reads (39%) | called by muse, mutect2, varscan2
- LRRC8C | c.1695C>T p.S565= | Silent (SNP) | VAF 84/191 reads (44%) | called by muse, mutect2, varscan2
- LRRC8E | c.847C>T p.L283= | Silent (SNP) | VAF 102/221 reads (46%) | catalogued as rs11667189; called by muse, mutect2, varscan2
- LSR | c.1245C>T p.F415= (on ENST00000361790; = p.F396= on NM_015925.6) | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs1202653548; called by muse, mutect2, varscan2
- MAP7D1 | c.1173C>T p.R391= | Silent (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- MARCKS | c.279C>T p.A93= | Silent (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- MED26 | c.1329G>A p.V443= | Silent (SNP) | VAF 33/282 reads (12%) | catalogued as rs375959752, COSV54662755; called by muse, mutect2, varscan2
- MEPCE | c.1374C>A p.T458= | Silent (SNP) | VAF 23/209 reads (11%) | called by muse, mutect2, varscan2
- MICAL3 | c.5298C>T p.S1766= | Silent (SNP) | VAF 16/157 reads (10%) | called by muse, mutect2, varscan2
- MMAA | c.912G>A p.A304= | Silent (SNP) | VAF 127/358 reads (35%) | catalogued as rs371769807, COSV99849919; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MMP28 | c.1551C>T p.S517= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs773505458; called by muse, mutect2, varscan2
- MMRN1 | c.576C>T p.S192= | Silent (SNP) | VAF 74/206 reads (36%) | called by muse, mutect2
- MROH7 | c.144T>C p.N48= | Silent (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2, varscan2
- MYCT1 | c.549G>A p.Q183= | Silent (SNP) | VAF 99/219 reads (45%) | called by muse, mutect2, varscan2
- N4BP2 | c.4074C>T p.T1358= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as rs554167780; called by muse, mutect2, varscan2
- NAV3 | c.4299G>A p.R1433= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as rs1196846391; called by muse, mutect2, varscan2
- NBR1 | c.738G>T p.G246= | Silent (SNP) | VAF 47/227 reads (21%) | called by muse, mutect2, varscan2
- NEUROD1 | c.1047G>A p.Q349= | Silent (SNP) | VAF 74/214 reads (35%) | called by muse, mutect2, varscan2
- NFS1 | c.582G>A p.Q194= | Silent (SNP) | VAF 12/139 reads (9%) | called by muse, mutect2
- NLRP6 | c.1537C>T p.L513= | Silent (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2
- NOTCH4 | c.3018C>T p.D1006= | Silent (SNP) | VAF 36/312 reads (12%) | catalogued as rs774972771, COSV66678733; called by muse, mutect2, varscan2
- NOTCH4 | c.2724C>T p.V908= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV66682527; called by muse, mutect2, varscan2
- NPIPB11 | c.1641G>A p.G547= | Silent (SNP) | VAF 413/1073 reads (38%) | called by muse, varscan2
- NR2F1 | c.723G>A p.P241= | Silent (SNP) | VAF 120/302 reads (40%) | catalogued as rs1391412175; called by muse, mutect2, varscan2
- NSMAF | c.2526C>A p.S842= | Silent (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- OAS3 | c.1582C>T p.L528= | Silent (SNP) | VAF 99/223 reads (44%) | called by muse, mutect2, varscan2
- OBSL1 | c.1203G>A p.R401= | Silent (SNP) | VAF 94/228 reads (41%) | called by muse, mutect2, varscan2
- OR4D11 | c.753T>C p.F251= | Silent (SNP) | VAF 66/224 reads (29%) | called by muse, mutect2, varscan2
- OVCH1 | c.3126C>T p.Y1042= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs181469786; called by muse, mutect2, varscan2
- PCDH19 | c.873C>T p.I291= | Silent (SNP) | VAF 44/248 reads (18%) | catalogued as COSV55271019; called by muse, mutect2, varscan2
- PCDHB2 | c.1560G>A p.S520= | Silent (SNP) | VAF 26/797 reads (3%) | catalogued as rs1398124097, COSV50580746, COSV50608706; called by muse, mutect2
- PLXNA2 | c.288G>T p.P96= | Silent (SNP) | VAF 33/270 reads (12%) | catalogued as rs148386352; called by muse, mutect2, varscan2
- PPP1R37 | c.1125C>T p.C375= | Silent (SNP) | VAF 60/126 reads (48%) | called by muse, mutect2, varscan2
- PRAMEF1 | c.813G>A p.L271= | Silent (SNP) | VAF 58/423 reads (14%) | called by muse, mutect2, varscan2
- RAB29 | c.366C>T p.L122= | Silent (SNP) | VAF 72/186 reads (39%) | catalogued as COSV99353132; called by muse, mutect2, varscan2
- RADIL | c.2997C>T p.G999= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs373930521; called by muse, mutect2, varscan2
- RASSF4 | c.945G>A p.E315= | Silent (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- RBM15 | c.1614G>A p.L538= | Silent (SNP) | VAF 55/131 reads (42%) | called by muse, mutect2, varscan2
- RFPL2 | c.489C>T p.H163= | Silent (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- SDK1 | c.1194T>C p.A398= | Silent (SNP) | VAF 50/153 reads (33%) | called by muse, mutect2, varscan2
- SERTAD1 | c.297G>A p.V99= | Silent (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.1263G>A p.R421= | Silent (SNP) | VAF 58/151 reads (38%) | called by muse, mutect2, varscan2
- SH3TC2 | c.2091T>C p.G697= | Silent (SNP) | VAF 238/544 reads (44%) | called by muse, mutect2, varscan2
- SLC1A3 | c.246C>A p.S82= | Silent (SNP) | VAF 105/330 reads (32%) | catalogued as COSV54318284; called by muse, varscan2
- SLC9A1 | c.450C>T p.G150= | Silent (SNP) | VAF 81/222 reads (36%) | catalogued as rs1467569903, COSV56054172; called by muse, mutect2, varscan2
- SMC1A | c.2700C>T p.G900= | Silent (SNP) | VAF 89/370 reads (24%) | catalogued as rs186510389, COSV59131879; called by muse, mutect2, varscan2
- SMIM20 | c.210C>A p.T70= | Silent (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2
- SYTL2 | c.1689T>C p.V563= (on ENST00000528231 / NM_001162951.2; = p.V579= on NM_032943.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/206 reads (37%) | catalogued as rs1231553762; called by muse, mutect2, varscan2
- TACC2 | c.6021G>A p.S2007= (on ENST00000334433; = p.S85= on NM_006997.4) | Silent (SNP) | VAF 106/268 reads (40%) | catalogued as rs756389507, COSV53284383; called by muse, mutect2, varscan2
- TENT4A | c.1425G>A p.P475= | Silent (SNP) | VAF 100/272 reads (37%) | catalogued as rs1455343400; called by muse, mutect2, varscan2
- TGM5 | c.678T>C p.C226= (on ENST00000220420 / NM_201631.4; = p.C144= on NM_004245.4) | Silent (SNP) | VAF 130/360 reads (36%) | called by muse, mutect2, varscan2
- TRO | c.4113A>G p.P1371= | Silent (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- TRPC4AP | c.783T>C p.D261= | Silent (SNP) | VAF 92/294 reads (31%) | catalogued as rs766853672; called by muse, varscan2
- TSHZ3 | c.594G>A p.R198= | Silent (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- TTR | c.195C>T p.A65= | Silent (SNP) | VAF 109/292 reads (37%) | called by muse, mutect2, varscan2
- UBE2G2 | c.90T>C p.N30= | Silent (SNP) | VAF 19/183 reads (10%) | catalogued as rs1555962341; called by muse, mutect2, varscan2
- USP40 | c.1425C>T p.Y475= | Silent (SNP) | VAF 54/146 reads (37%) | called by muse, mutect2, varscan2
- UVSSA | c.1485G>A p.E495= | Silent (SNP) | VAF 51/237 reads (22%) | called by muse, mutect2, varscan2
- VPS13B | c.1530C>T p.R510= | Silent (SNP) | VAF 93/256 reads (36%) | catalogued as rs149919865; ClinVar: likely benign; called by muse, mutect2, varscan2
- VWC2 | c.495C>T p.I165= | Silent (SNP) | VAF 51/196 reads (26%) | catalogued as rs954405226; called by muse, mutect2, varscan2
- WDR24 | c.1333C>T p.L445= (on ENST00000248142; = p.L315= on NM_032259.4) | Silent (SNP) | VAF 66/272 reads (24%) | catalogued as COSV99555965; called by muse, mutect2, varscan2
- WDR54 | c.384C>T p.A128= | Silent (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
- XYLT2 | c.1449C>T p.N483= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as rs1340952379; called by muse, mutect2, varscan2
- ZFHX4 | c.342C>T p.S114= | Silent (SNP) | VAF 10/247 reads (4%) | catalogued as rs1366529219, COSV51497654, COSV99260630; called by muse, mutect2
- ZNF197 | c.2928T>C p.H976= | Silent (SNP) | VAF 28/146 reads (19%) | called by muse, mutect2, varscan2
- ZNF541 | c.1347G>T p.P449= | Silent (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- ZNF730 | c.312A>G p.K104= | Silent (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- AC093155.3 | c.767-1238C>T | Intron (SNP) | VAF 47/102 reads (46%) | catalogued as rs1312057414; called by muse, mutect2, varscan2
- AC107023.1 | n.25+3065G>A | Intron (SNP) | VAF 73/183 reads (40%) | called by muse, mutect2, varscan2
- AF186192.2 | n.75C>T | RNA (SNP) | VAF 21/139 reads (15%) | catalogued as rs1276297669; called by muse, mutect2, varscan2
- AKR1C3 | c.369+37C>T | Intron (SNP) | VAF 45/248 reads (18%) | catalogued as rs782687251; called by muse, mutect2, varscan2
- ALDH1A2 | c.-43G>A | 5'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, varscan2
- AP000769.5 | chr11:65499156 del A | 5'Flank (DEL) | VAF 10/61 reads (16%) | catalogued as rs761315580; called by mutect2, pindel, varscan2
- ARHGAP27P2 | n.507G>A | RNA (SNP) | VAF 22/153 reads (14%) | called by muse, mutect2, varscan2
- ASF1B | c.*55C>T | 3'UTR (SNP) | VAF 65/127 reads (51%) | catalogued as rs1415012455; called by muse, mutect2, varscan2
- ATF6B | c.-5del | 5'UTR (DEL) | VAF 18/128 reads (14%) | catalogued as rs752972166; called by pindel, varscan2
- C4B | c.3154+31del | Intron (DEL) | VAF 33/142 reads (23%) | catalogued as rs1386109602; called by mutect2, pindel, varscan2
- CAMKMT | c.376+66319dup | Intron (INS) | VAF 13/116 reads (11%) | called by mutect2, pindel, varscan2
- CGB3 | c.-5C>A | 5'UTR (SNP) | VAF 47/135 reads (35%) | catalogued as rs1430663977; called by muse, mutect2, varscan2
- CHRNA4 | c.*1665del | 3'UTR (DEL) | VAF 12/121 reads (10%) | called by mutect2, pindel, varscan2
- CHUK | c.2108+19A>G | Intron (SNP) | VAF 44/280 reads (16%) | called by muse, mutect2, varscan2
- CLCN5 | c.17-39123A>G | Intron (SNP) | VAF 27/168 reads (16%) | catalogued as rs1446486713; called by muse, mutect2, varscan2
- CLYBL | chr13:99606683 G>A | 5'Flank (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- COMT | c.484-41_484-39del | Intron (DEL) | VAF 71/536 reads (13%) | called by pindel, varscan2
- CROT | c.116-1631C>T | Intron (SNP) | VAF 70/157 reads (45%) | catalogued as rs776864214; called by muse, mutect2, varscan2
- CTSC | c.757+9del | Intron (DEL) | VAF 76/219 reads (35%) | called by mutect2, pindel, varscan2
- DCAF6 | c.2166+25del | Intron (DEL) | VAF 51/260 reads (20%) | called by mutect2, pindel, varscan2
- EIPR1 | c.516+5411C>A | Intron (SNP) | VAF 20/257 reads (8%) | called by muse, mutect2
- ENDOV | c.229-2205T>C | Intron (SNP) | VAF 63/188 reads (34%) | called by muse, mutect2, varscan2
- ERGIC2 | c.*54del | 3'UTR (DEL) | VAF 46/164 reads (28%) | catalogued as rs1200700597; called by mutect2, varscan2
- ETDB | chrX:135123373 G>A | 5'Flank (SNP) | VAF 104/306 reads (34%) | called by muse, mutect2, varscan2
- FAM207A | chr21:44939549 A>G | 5'Flank (SNP) | VAF 42/252 reads (17%) | called by muse, mutect2, varscan2
- FBXL19 | c.*654C>T | 3'UTR (SNP) | VAF 18/91 reads (20%) | catalogued as rs1188974630; called by muse, mutect2, varscan2
- FCN2 | c.*45del | 3'UTR (DEL) | VAF 18/172 reads (10%) | catalogued as rs113204016; called by mutect2, pindel
- FEM1A | c.*12C>T | 3'UTR (SNP) | VAF 19/35 reads (54%) | catalogued as rs371307016; called by muse, mutect2, varscan2
- FOXP1 | c.*935del | 3'UTR (DEL) | VAF 16/74 reads (22%) | catalogued as rs544766693; called by mutect2, varscan2
- FXR1 | c.1603+733del | Intron (DEL) | VAF 6/47 reads (13%) | catalogued as rs769011065; called by mutect2, varscan2
- GAMT | c.570+51G>T | Intron (SNP) | VAF 44/245 reads (18%) | called by muse, mutect2, varscan2
- GNA14 | c.-10T>G | 5'UTR (SNP) | VAF 105/277 reads (38%) | catalogued as COSV59023364; called by muse, mutect2, varscan2
- GORAB | c.*51del | 3'UTR (DEL) | VAF 78/271 reads (29%) | called by mutect2, pindel, varscan2
- GPR89B | chr1:147995668 A>G | 3'Flank (SNP) | VAF 16/288 reads (6%) | called by muse, mutect2
- GSTO2 | c.-68C>T | 5'UTR (SNP) | VAF 74/216 reads (34%) | catalogued as COSV58538814; called by muse, mutect2, varscan2
- HERC4 | c.1926+58del | Intron (DEL) | VAF 22/93 reads (24%) | called by mutect2, varscan2
- HERC6 | c.200-23del | Intron (DEL) | VAF 18/126 reads (14%) | catalogued as rs747737859; called by pindel, varscan2
- HOXC4 | c.-124+16623del | Intron (DEL) | VAF 41/219 reads (19%) | called by mutect2, pindel, varscan2
- HS6ST1 | c.*35del | 3'UTR (DEL) | VAF 14/105 reads (13%) | catalogued as COSV99389411; called by mutect2, pindel, varscan2
- HUS1 | c.465+334A>G | Intron (SNP) | VAF 62/179 reads (35%) | called by muse, mutect2, varscan2
- ITGB3BP | c.485-18del | Intron (DEL) | VAF 15/64 reads (23%) | catalogued as rs111866553; called by pindel, varscan2
- LMF1 | c.514+2580A>G | Intron (SNP) | VAF 54/133 reads (41%) | called by muse, mutect2, varscan2
- MAN1B1 | c.1446-21G>A | Intron (SNP) | VAF 96/224 reads (43%) | called by muse, mutect2, varscan2
- MAP2K1 | c.1022+55dup | Intron (INS) | VAF 88/249 reads (35%) | called by mutect2, pindel, varscan2
- MAX | c.-25G>A | 5'UTR (SNP) | VAF 48/153 reads (31%) | called by muse, mutect2, varscan2
- MEST | c.-27C>T | 5'UTR (SNP) | VAF 7/17 reads (41%) | catalogued as rs1311542533; called by muse, mutect2, varscan2
- MGAT4A | c.*26del | 3'UTR (DEL) | VAF 10/96 reads (10%) | catalogued as rs746717825; called by mutect2, pindel, varscan2
- MST1L | n.185C>T | RNA (SNP) | VAF 95/466 reads (20%) | catalogued as rs773742848; called by muse, mutect2, varscan2
- NDUFB10 | chr16:1965321 del C | 3'Flank (DEL) | VAF 52/148 reads (35%) | catalogued as rs747554929; called by mutect2, pindel, varscan2
- NOTCH3 | c.*44C>T | 3'UTR (SNP) | VAF 74/173 reads (43%) | catalogued as rs749913764; called by muse, mutect2, varscan2
- PARGP1 | n.763del | RNA (DEL) | VAF 122/536 reads (23%) | called by mutect2, varscan2
- PDIA3P1 | chr1:147179242 C>T | 3'Flank (SNP) | VAF 22/679 reads (3%) | called by muse, mutect2
- PDPN | c.-107C>T | 5'UTR (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- PI4KAP2 | n.2371del | RNA (DEL) | VAF 38/134 reads (28%) | called by mutect2, pindel, varscan2
- POLR1C | c.806-20del | Intron (DEL) | VAF 105/278 reads (38%) | called by mutect2, pindel, varscan2
- PPP6R3 | c.*1917C>G | 3'UTR (SNP) | VAF 169/458 reads (37%) | called by muse, mutect2, varscan2
- PRKCZ | c.975-175C>T | Intron (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- RNF217-AS1 | n.3445del | RNA (DEL) | VAF 6/22 reads (27%) | catalogued as rs1218500737; called by mutect2, pindel, varscan2
- SAMD3 | c.654+750_654+755delinsCC | Intron (DEL) | VAF 5/44 reads (11%) | called by pindel, varscan2*
- SCO1 | c.364+28T>C | Intron (SNP) | VAF 65/301 reads (22%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3194C>T | RNA (SNP) | VAF 100/288 reads (35%) | catalogued as rs751890544; called by muse, mutect2, varscan2
- SLC6A13 | c.479-263C>A | Intron (SNP) | VAF 45/280 reads (16%) | called by muse, mutect2, varscan2
- SLC8A3 | c.1785-2943dup | Intron (INS) | VAF 22/120 reads (18%) | called by mutect2, pindel, varscan2
- SNORD116-21 | n.7A>C | RNA (SNP) | VAF 187/526 reads (36%) | called by muse, mutect2, varscan2
- SPATA13 | c.290-5336del | Intron (DEL) | VAF 50/164 reads (30%) | catalogued as rs749470297; called by mutect2, varscan2
- SRRM2 | c.690-39del | Intron (DEL) | VAF 48/157 reads (31%) | called by pindel, varscan2
- TMC7 | c.2106+27A>G | Intron (SNP) | VAF 58/381 reads (15%) | called by muse, mutect2, varscan2
- TMEM242 | c.327+49A>G | Intron (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- TRDN | c.1369+11del | Intron (DEL) | VAF 37/100 reads (37%) | catalogued as rs537388823; ClinVar: uncertain significance; called by mutect2, varscan2
- TRIM51EP | n.978del | RNA (DEL) | VAF 52/140 reads (37%) | catalogued as rs752808275; called by mutect2, pindel, varscan2
- USP15 | chr12:62417182 del G | 3'Flank (DEL) | VAF 14/65 reads (22%) | catalogued as rs766005728; called by pindel, varscan2
- WNT3A | c.-55del | 5'UTR (DEL) | VAF 9/68 reads (13%) | catalogued as rs974318419, COSV52731071; called by mutect2, varscan2
- WWOX | c.1056+324201C>T | Intron (SNP) | VAF 73/187 reads (39%) | catalogued as rs183422261; called by muse, mutect2, varscan2
- XXYLT1 | c.785+34358A>G | Intron (SNP) | VAF 37/213 reads (17%) | called by muse, mutect2, varscan2
- ZCCHC24 | c.*33del | 3'UTR (DEL) | VAF 39/138 reads (28%) | catalogued as rs759518581; called by mutect2, pindel, varscan2
- ZFAT | c.-22del | 5'UTR (DEL) | VAF 18/130 reads (14%) | catalogued as rs746459398; called by mutect2, varscan2
- ZSWIM8 | c.-27dup | 5'UTR (INS) | VAF 24/64 reads (38%) | catalogued as rs767495122; called by mutect2, varscan2
